Somatic mutation profile of tumor specimen MMRF_1189_1_BM_CD138pos (aliquot MMRF_1189_1_BM_CD138pos_T2_TSE61_K03414) from MMRF case MMRF_1189, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,830 days).
Specimen MMRF_1189_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41169a35-ec7f-492a-88f0-ef7f6727e1ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1189_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1189_1_PB_Whole_C1_TSE61_K03416; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018dc36d-28d3-4f02-89b7-388507fb4efb

The open-access MAF lists 79 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 19, Silent 16, 5'UTR 7, 3'Flank 4, Intron 3, 5'Flank 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP170B | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1486977164; called by muse, mutect2, varscan2
- CPN1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs754989179; called by muse, mutect2, varscan2
- DPF3 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63499012; called by muse, mutect2, varscan2
- EPHA7 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs745460482, COSV65168735; called by muse, mutect2, varscan2
- GXYLT2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs200557116, COSV67473873; called by muse, mutect2, varscan2
- LRRK2 | c.5327T>G p.L1776R | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54165377; called by muse, mutect2, varscan2
- MMGT1 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.146); catalogued as COSV60004187; called by muse, mutect2, varscan2
- NPR2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs748364573; called by muse, mutect2, varscan2
- NRG3 | c.1240del p.A414Qfs*7 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as COSV100931751; called by mutect2, pindel, varscan2
- OR4C16 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201228188; called by muse, mutect2, varscan2
- PGGHG | c.513dup p.P172Afs*22 | Frame Shift Ins (INS) | VAF 21/104 reads (20%) | catalogued as rs774965357; called by mutect2, pindel, varscan2
- PRKCD | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57847442; called by muse, mutect2, varscan2
- SLC28A2 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751869186; called by muse, mutect2, varscan2
- TJP3 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778173275; called by muse, mutect2, varscan2
- UPF3B | c.1411G>A p.E471K (on ENST00000276201 / NM_080632.3; = p.E458K on NM_023010.3) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52231501; called by muse, mutect2, varscan2
- ARHGAP35 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ERCC2 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HCFC1 | c.5423A>T p.K1808M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC12 | c.5606C>T p.T1869I (on ENST00000379442; = p.T1726I on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/810 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MYO1F | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PER2 | c.3589G>T p.G1197C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- POGZ | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SYT1 | c.328T>A p.L110I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TMEM151A | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM60 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WTAP | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP62 | c.1639G>A p.G547S (on ENST00000502412 / NM_001377944.1; = p.G514S on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ANO10 | c.498C>T p.I166= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs781594739; called by muse, mutect2, varscan2
- DEK | c.21T>A p.A7= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- EP400 | c.8790G>A p.L2930= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100201831; called by muse, mutect2, varscan2
- EPS8L2 | c.1434C>T p.V478= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- H2AC20 | c.237C>T p.I79= | Silent (SNP) | VAF 255/376 reads (68%) | catalogued as COSV58612626; called by muse, mutect2, varscan2
- HASPIN | c.924C>T p.A308= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV54000215; called by muse, mutect2, varscan2
- NFIB | c.354C>T p.I118= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs563322451; called by muse, mutect2, varscan2
- PCDH19 | c.2695T>C p.L899= (on ENST00000373034 / NM_001184880.2; = p.L851= on NM_020766.3) | Silent (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- PRKCZ | c.834C>T p.Y278= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs543820208; called by muse, mutect2, varscan2
- SLC6A14 | c.1347C>A p.P449= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- TSPAN7 | c.72C>T p.F24= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as COSV54530506; called by muse, mutect2, varscan2
- VCAN | c.3927G>C p.T1309= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV54102393; called by muse, mutect2, varscan2
- XK | c.354T>A p.I118= | Silent (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- XPO5 | c.795G>A p.L265= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- ZNF480 | c.876T>C p.C292= | Silent (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- ZNF560 | c.459C>T p.L153= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs747698465; called by muse, mutect2, varscan2
- ACAP2 | c.*3960C>T | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ACTC1 | chr15:34790178 C>T | 3'Flank (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.*836C>T | 3'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs866192439; called by muse, mutect2, varscan2
- BEX3 | c.-184G>T | 5'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95157334 T>C | 3'Flank (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- CPA6 | c.-191T>G | 5'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- CYB561A3 | c.-156G>A | 5'UTR (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2
- EIF4EBP2 | c.*774C>T | 3'UTR (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- FAM120C | c.*4380dup | 3'UTR (INS) | VAF 21/44 reads (48%) | called by mutect2, varscan2
- GPM6A | c.*925C>A | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- GRIK2 | c.*1149del | 3'UTR (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- HCFC1 | c.-16A>G | 5'UTR (SNP) | VAF 135/269 reads (50%) | called by muse, mutect2, varscan2
- KCTD15 | c.694-233G>A | Intron (SNP) | VAF 29/59 reads (49%) | catalogued as rs568630368; called by muse, mutect2, varscan2
- LANCL1 | chr2:210433510 T>A | 3'Flank (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- LRRC8E | c.-57C>T | 5'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- NEDD8 | c.-93G>A | 5'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- NR2F2 | c.*1285T>C | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- NTS | c.*514A>G | 3'UTR (SNP) | VAF 10/23 reads (43%) | catalogued as rs1565772185; called by muse, mutect2, varscan2
- NXPE3 | c.-339T>G | 5'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- OTUD5 | chrX:48922060 A>C | 3'Flank (SNP) | VAF 24/52 reads (46%) | called by muse, varscan2
- PIM2 | c.*606A>C | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- PRUNE2 | c.*2314A>G | 3'UTR (SNP) | VAF 9/83 reads (11%) | catalogued as rs1292010531; called by muse, mutect2, varscan2
- PTPRT | c.*1362C>T | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- RAD1 | c.*499G>A | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1361394483; called by muse, varscan2
- RAD23B | c.*1435G>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | catalogued as rs916401923; called by muse, mutect2, varscan2
- RUNX1T1 | c.*626A>C | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+1164C>T | Intron (SNP) | VAF 26/68 reads (38%) | called by muse, varscan2
- SETD1B | c.*901C>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- SPATA6L | chr9:4666554 G>A | 5'Flank (SNP) | VAF 32/75 reads (43%) | catalogued as rs1296244976; called by muse, mutect2, varscan2
- SUGP2 | c.*1142T>G | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- TMEM53 | c.*137C>G | 3'UTR (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*2C>T | 3'UTR (SNP) | VAF 12/44 reads (27%) | catalogued as rs1451952820; called by muse, mutect2, varscan2
- VIM | chr10:17228461 A>T | 5'Flank (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- ZNF345 | c.*928C>T | 3'UTR (SNP) | VAF 50/114 reads (44%) | catalogued as COSV100080282; called by muse, mutect2, varscan2
- ZNF765 | c.*87A>G | 3'UTR (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
